TCGA case TCGA-HS-A5N8 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Ontario Institute for Cancer Research (OICR). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/724edf28-c9b2-4b11-ae30-70a137f821b8

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 69 years; Vital status: Dead; Days to death: 22 days.

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 69.9 years (25,549 days); Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Sites of involvement: Uterus; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 9.5; Tumor width measurement: 10.
   Pathology details: Consistent pathology review: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Tumor burden: 10.

Follow-up (2 entries)
- Days to follow up: 3 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 22.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 30.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HS-A5N8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 830 mg.
  Slide TCGA-HS-A5N8-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HS-A5N8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HS-A5N8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Disease multifocal indicator: No; Tumor burden pathologic: 10.0.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Partial Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 22 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 22 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 22 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HS-A5N8-01A-11D-A26F-01): tumor purity 0.74, ploidy 2.85, whole-genome doublings 1.
